FM case AD4378 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/5f8e360e-f11c-4ca2-8a70-8e3b840829e4

Female, 74.3 years: Duct carcinoma, NOS (ICD-O-3 8500/3) of the major salivary gland; primary biopsied or resected from the major salivary gland. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
